Somatic mutation profile of tumor specimen TCGA-AR-A24N-01A (aliquot TCGA-AR-A24N-01A-11D-A167-09) from TCGA case TCGA-AR-A24N, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 54.7 years (19,989 days).
Specimen TCGA-AR-A24N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6dbc268-da16-4d0f-88a4-dacdd782b83c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24N-10A (Blood Derived Normal), aliquot TCGA-AR-A24N-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc9561fa-5c99-41a6-880a-d1126ae4d36d

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 3, RNA 1, 5'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf24 | c.26G>C p.W9S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV58504918; called by muse, mutect2, varscan2
- CACNA1B | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1037362457, COSV53113700; called by muse, mutect2, varscan2
- CWC25 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs555146635; called by muse, mutect2, varscan2
- FOXK2 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV58876914; called by muse, mutect2, varscan2
- HIPK1 | c.3566G>A p.R1189Q (on ENST00000369558 / NM_001369806.1; = p.R795Q on NM_181358.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs142071670; called by muse, mutect2, varscan2
- HNRNPH2 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100346883; called by muse, mutect2, varscan2
- KCNA5 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0.021); catalogued as rs778864235, COSV52903870; called by muse, mutect2, varscan2
- KCNK9 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57278087; called by muse, mutect2, varscan2
- KMT2C | c.9934C>T p.Q3312* | Nonsense Mutation (SNP) | VAF 54/127 reads (43%) | catalogued as COSV51289396; called by muse, mutect2, varscan2
- NEGR1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60830627; called by muse, mutect2, varscan2
- NPIPB15 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV70436568; called by mutect2, varscan2
- PCDHGA11 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV53898387; called by muse, mutect2, varscan2
- PRRG2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs538503371, COSV55869504; called by muse, mutect2, varscan2
- PTAR1 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV100466314; called by muse, mutect2
- SAMD4A | c.570G>T p.W190C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51876669; called by muse, mutect2, varscan2
- SHANK1 | c.5990G>A p.R1997Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs779905112, COSV53242956; called by muse, mutect2, varscan2
- SLC22A9 | c.507-2A>T p.X169_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99654730; called by muse, mutect2, varscan2
- TAAR5 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1422223401, COSV99236823; called by muse, mutect2
- TGM2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs768583570, COSV63931056; called by muse, mutect2, varscan2
- TP53BP2 | c.3279C>G p.I1093M (on ENST00000343537 / NM_001031685.3; = p.I964M on NM_005426.2) | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV59066300; called by muse, mutect2, varscan2
- TTN | c.48652C>A p.P16218T (on ENST00000591111; = p.P8794T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV100594354, COSV100612312; called by muse, mutect2
- UBN1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs773370430, COSV52165662; called by muse, mutect2, varscan2
- UBQLN3 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV61163193; called by muse, mutect2, varscan2
- VRK1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV53707889; called by muse, mutect2, varscan2
- WFIKKN2 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100259727; called by muse, mutect2
- ZNF285 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs187757032, COSV58407943; called by muse, mutect2, varscan2
- ZNF429 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs780017355, COSV61914430; called by muse, mutect2, varscan2
- ZNF451 | c.2552C>A p.S851* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100674624; called by muse, mutect2
- ZNF623 | c.910T>C p.S304P | Missense Mutation (SNP) | VAF 101/136 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV71697083; called by muse, mutect2, varscan2
- UBC | c.1687dup p.Q563Pfs*9 | Frame Shift Ins (INS) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2283G>T p.V761= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99683004; called by muse, mutect2
- MUC5B | c.1446G>A p.T482= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs562331900, COSV71589962; called by muse, mutect2, varscan2
- NFATC2 | c.2334G>A p.A778= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs374907981; called by muse, mutect2, varscan2
- PRR16 | c.891G>A p.R297= (on ENST00000407149 / NM_001300783.2; = p.R274= on NM_016644.2) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101086120, COSV65394765; called by muse, mutect2, varscan2
- RECQL | c.420G>A p.L140= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV59084308; called by muse, mutect2, varscan2
- STUB1 | c.597C>T p.C199= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV50196362; called by muse, mutect2, varscan2
- WASHC5 | c.2829G>A p.A943= | Silent (SNP) | VAF 34/234 reads (15%) | catalogued as rs369339497; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF548 | c.126C>T p.A42= | Silent (SNP) | VAF 68/158 reads (43%) | catalogued as COSV60240278; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084906 C>A | 5'Flank (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100811002; called by muse, mutect2, varscan2
- OR2W5 | n.1067G>A | RNA (SNP) | VAF 5/36 reads (14%) | catalogued as rs532925117; called by muse, mutect2, varscan2
